FM case AD5779 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Adenomas and Adenocarcinomas; Primary site: Uterus, NOS.
https://portal.gdc.cancer.gov/cases/06df0016-05c5-4ca4-a639-b9a3ce53f7b4

Female, 50.5 years: Adenocarcinoma, NOS (ICD-O-3 8140/3) of the uterus; metastasis biopsied or resected from the liver. Tumor nuclei on the sequenced sample's slide: 50% (pathologist estimate recorded by GDC). Sample type: Metastatic.
